Somatic mutation profile of tumor specimen 0DRY80 from CCDI case PBCADX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.0 years (6,204 days).
Specimen 0DRY80: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 054a4beb-c56e-43a7-8f8c-26e85f80675a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY82 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83a5976-4ec8-4bb7-ae55-54e4d5115827

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 247/886 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RXYLT1 | c.553_554insTAAATTTTGTGCATAAAGTAACCACTGGGTGGCAT p.Q185Lfs*15 | Frame Shift Ins (INS) | VAF 28/860 reads (3%) | called by muse*, mutect2
- CSPP1 | c.24C>T p.A8= | Silent (SNP) | VAF 23/505 reads (5%) | catalogued as rs988655476, COSV51583853; called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 10/340 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/238 reads (11%) | called by muse, varscan2
